Somatic mutation profile of tumor specimen TCGA-A3-A6NJ-01A (aliquot TCGA-A3-A6NJ-01A-12D-A33K-10) from TCGA case TCGA-A3-A6NJ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.3 years (20,918 days).
Specimen TCGA-A3-A6NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe4d3505-0404-4980-a79e-79bd37480dc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A6NJ-10A (Blood Derived Normal), aliquot TCGA-A3-A6NJ-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c246ff5d-75d4-4ba4-9719-88f87c8a3fc4

The open-access MAF lists 54 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100253436; called by muse, mutect2, varscan2
- ABLIM2 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1561383421, COSV99590566, COSV99590860; called by muse, mutect2, varscan2
- ACAN | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100719464; called by muse, mutect2, varscan2
- ACSS3 | c.636T>A p.D212E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.78); catalogued as COSV99699651; called by mutect2, varscan2
- ADAM17 | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176640; called by muse, mutect2, varscan2
- ADGRG4 | c.3119C>A p.A1040D | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV99797525; called by muse, mutect2, varscan2
- ASH1L | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV100853652; called by muse, mutect2, varscan2
- CARMIL3 | c.3707G>A p.S1236N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as COSV99393415, COSV99393903; called by muse, mutect2, varscan2
- CCDC183 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV100566093; called by muse, mutect2, varscan2
- CCDC40 | c.1468G>T p.V490L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs200902099, COSV99482317; called by muse, mutect2, varscan2
- CCNF | c.1017C>G p.D339E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53544007, COSV99564315; called by mutect2, varscan2
- CHRM2 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV100282207; called by muse, mutect2, varscan2
- CUBN | c.2192C>A p.T731N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64709407, COSV64721187; called by muse, mutect2, varscan2
- DCAF17 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100930800; called by muse, mutect2, varscan2
- DNASE2 | c.547A>G p.N183D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99263944; called by muse, mutect2
- DOP1A | c.3288T>A p.F1096L | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV99383192; called by muse, mutect2, varscan2
- DST | c.21718C>T p.P7240S (on ENST00000361203 / NM_001374722.1; = p.P4937S on NM_015548.5) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55018361; called by muse, mutect2, varscan2
- ERBB4 | c.3110C>G p.S1037C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV100728552, COSV61523027; called by muse, mutect2, varscan2
- ERICH5 | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100582917; called by muse, mutect2, varscan2
- FANCI | c.2855C>G p.T952S (on ENST00000310775 / NM_001376911.1; = p.T892S on NM_018193.3) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100168741; called by muse, mutect2, varscan2
- GP2 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100221698; called by muse, mutect2, varscan2
- ICAM4 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.134); catalogued as COSV99321245; called by muse, mutect2, varscan2
- ICAM4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.104); catalogued as COSV99321247; called by muse, mutect2, varscan2
- IQCG | c.9-1G>C p.X3_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV54566254, COSV99502833; called by muse, mutect2, varscan2
- IRF2 | c.494T>A p.I165K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV101165925; called by muse, mutect2
- KIAA1549L | c.3032T>C p.F1011S (on ENST00000321505; = p.F1308S on NM_012194.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV99684763; called by muse, mutect2, varscan2
- LIPF | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 23/185 reads (12%) | catalogued as COSV99490700; called by muse, mutect2, varscan2
- MLH3 | c.4253A>G p.N1418S (on ENST00000355774 / NM_001040108.2; = p.N1394S on NM_014381.3) | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1258839619, COSV99470796; called by muse, mutect2
- NAV2 | c.7066G>A p.V2356M (on ENST00000396087 / NM_001244963.2; = p.V2297M on NM_145117.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217807; called by muse, mutect2, varscan2
- SATL1 | c.1268G>A p.G423D (on ENST00000395409; = p.G610D on NM_001012980.2) | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261165; called by muse, mutect2
- SLC44A2 | c.1911T>A p.Y637* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100213545; called by muse, mutect2
- SLC6A15 | c.1940A>T p.D647V | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV99881715; called by muse, mutect2, varscan2
- SLC6A15 | c.1939G>T p.D647Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99881717; called by muse, mutect2, varscan2
- SNX16 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as COSV100629733; called by muse, mutect2, varscan2
- TMEM214 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99476598; called by muse, mutect2
- TRAPPC8 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1287617188, COSV99352202; called by muse, mutect2, varscan2
- ZMYM2 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101244202; called by muse, mutect2, varscan2
- ZNF875 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100183625; called by muse, mutect2, varscan2
- ALKBH1 | c.1073_1084del p.I358_E361del | In Frame Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- CTNNA1 | c.2574_2576del p.W859del | In Frame Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- JSRP1 | c.153_154del p.Q52Gfs*3 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by pindel, varscan2
- PBRM1 | c.3645_3646dup p.F1216Yfs*3 (on ENST00000296302 / NM_001366071.2; = p.F1191Yfs*3 on NM_018313.5) | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- PCDHGB4 | c.1372dup p.H458Pfs*19 | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- ZNF790 | c.1125del p.F375Lfs*278 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- ADCY2 | c.2682G>A p.P894= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs201615098; called by muse, mutect2, varscan2
- DCLRE1C | c.1204A>C p.R402= (on ENST00000378278 / NM_001350965.2; = p.R287= on NM_022487.4) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100543238; called by muse, mutect2, varscan2
- HOGA1 | c.621G>C p.L207= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV101035583; called by muse, mutect2, varscan2
- IRF2 | c.492T>A p.T164= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV101165926; called by muse, mutect2
- LRP1 | c.1131C>T p.V377= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99677827; called by muse, mutect2
- NLRP12 | c.1452C>T p.H484= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs769866276, COSV60755872; called by muse, mutect2, varscan2
- OR4C12 | c.333C>A p.I111= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100078322, COSV100078759; called by muse, mutect2, varscan2
- RIMBP3 | c.2706C>T p.I902= | Silent (SNP) | VAF 36/428 reads (8%) | called by muse, mutect2
- TUSC3 | c.6G>T p.G2= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101143112; called by muse, mutect2
- NDUFV2 | c.54+2170_54+2171del | Intron (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
